Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A025, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A025-01A (Primary Tumor).

Internal Sample ID

Diagnosis:

Tubular adenoma of the sigmoid in No. 1 (low-grade intra-epithelial neoplasia).

Well-differentiated, invasive adenocarcinoma of the sigmoid in No. 2, arising from a tubular adenoma with atypia and with infiltration of the submucosa.

Tumor classification:

M-8210/3, G1

This is chronic appendicitis with obliteration of the lumen by scar tissue, with an acute inflammatory flare in the outer wall layers with eosinophilia, acute fibrinous granulocytic serositis (in I.), a rectal resection specimen with a mucosal-submucosal defect in the area marked with a clip, perifocal, granulating inflammation, polypous hyperplasia of the rectal mucosa in the area of the margin (block A), wall perforation (block B), acute hemorrhage, necrosis, acute perifocal inflammation, acute serositis (in II.), moderate reactive lymphadenitis (in II. and IV.), an anastomosis ring with a diverticulum (in III.) and normally layered plain sections from all other labeled specimen segments (in II., IV. and V.).

No evidence of specificity or malignancy.

15+

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: rectum C20.9 to 3/3/11

HtPA Discrepancy		
Cases (circle):		
Reviewed Initials		
Reviewed Date		

5/10/11

Source: NCI Genomic Data Commons file 906d59ae-eb6d-48d3-a764-11275fee1aa9 (TCGA-AG-A025.390DADDE-F6CC-4072-B56C-C83EEE9AB337.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).